Gene-level copy-number profile of tumor specimen TARGET-10-PATLPN-03A from TARGET case TARGET-10-PATLPN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (945 days).
Specimen TARGET-10-PATLPN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.ebf3405a-621c-5ad0-9e8e-12e21d957afb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATLPN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/d8f8703c-8e41-402f-80fa-2d2a9aa153ef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 2,499; copy number 2: 55,219; copy number 3: 2,491.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr7:38,291,616–38,318,861, 5 genes (within-gene range 0–2): TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,440,883–142,786,224, 46 genes: TRBV12-2, TRBV6-5, TRBV7-4, TRBV5-4, TRBV6-6, TRBV7-5, TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
